Gene-level copy-number profile of tumor specimen TCGA-DX-A2J1-01A from TCGA case TCGA-DX-A2J1, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Dedifferentiated liposarcoma; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 54.0 years (19,707 days).
Specimen TCGA-DX-A2J1-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.3619340b-8184-4cca-8c4e-0124058aa019.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DX-A2J1-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/22afc173-db7b-475e-b6e3-e536f3c28e4d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 2,382; copy number 2: 56,435; copy number 3: 452; copy number 4: 104; copy number 5: 38; copy number 6: 45; copy number 7: 170; copy number 8: 32; copy number 9: 16; copy number 10: 34; copy number 11: 5; copy number 12: 35; copy number 13: 23; copy number 14: 32; copy number 15: 1; copy number 16: 1; copy number 17: 1; copy number 18: 12; copy number 22: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DX-A2J1-01A-11D-A21P-01): tumor purity 0.71, ploidy 2.05, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 446 genes in 34 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:16,973,275–17,634,105, 12 genes, copy number 8: AC106894.1, MTND5P4, LINC02493, SNORA75B, RPS7P6, QDPR, CLRN2, NACAP5, AC006160.2, LAP3, AC006160.1, MED28.
- chr6:109,483,638–111,259,034, 32 genes, copy number 6 (within-gene range 4–6): AL109947.1, AK9, FIG4, GPR6, AL590009.1, WASF1, CDC40, METTL24, AL050350.1, DDO, SLC22A16, RN7SL617P, AC002464.1, AL512430.3, AL512430.4, CDK19, AL512430.1, AL512430.2, AL603914.1, RNU6-957P, SNORA40C, RNU6-1115P, CNN2P9, Z84480.1, AMD1, AL357515.1, GTF3C6, RPF2, GSTM2P1, SLC16A10, RNU6-960P, AL360227.1.
- chr6:134,917,393–144,853,034, 156 genes, copy number 7 (within-gene range 2–7) (broad region; genes not listed).
- chr6:152,898,047–153,347,488, 9 genes, copy number 5 (within-gene range 2–5): TUBB4BP7, AL080276.1, FBXO5, AL080276.2, MTRF1L, RGS17, RNA5SP224, AL590867.1, AL590867.2.
- chr9:112,997,120–113,164,140, 11 genes, copy number 14 (within-gene range 2–14): ZNF883, ZFP37, AL162588.1, AL449105.1, AL449105.3, AL449105.4, AL449105.2, AL449105.5, FAM225B, FAM225A, SLC31A2.
- chr9:114,060,127–114,312,511, 4 genes, copy number 6: AMBP, KIF12, COL27A1, MIR455.
- chr11:68,754,620–68,942,852, 5 genes, copy number 7 (within-gene range 2–7): CPT1A, LINC02701, MRPL21, IGHMBP2, AP000808.1.
- chr11:69,000,765–69,372,512, 13 genes, copy number 9–18: AP003071.4, AP003071.3, MRGPRF, MRGPRF-AS1, TPCN2, AP003071.5, MIR3164, AP003071.1, AP003071.2, SMIM38, MYEOV, IFITM9P, AP005233.2.
- chr11:69,641,156–69,819,416, 6 genes, copy number 8: CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3.
- chr11:70,203,296–70,398,488, 10 genes, copy number 5: FADD, AP000879.1, PPFIA1, H2AZP4, AP002336.2, MIR548K, AP002336.1, AP002336.3, AP000487.2, AP000487.1.
- chr11:82,689,559–82,733,864, 2 genes, copy number 9: RPS28P7, FAM181B.
- chr11:91,794,319–91,993,255, 3 genes, copy number 12 (within-gene range 2–12): LINC02756, TUBB4BP4, AP002799.1.
- chr11:101,915,010–102,955,732, 34 genes, copy number 10 (within-gene range 2–10): CEP126, CFAP300, RNA5SP535, AP001527.1, AP001527.2, YAP1, AP000942.2, AP000942.1, AP000942.3, AP000942.4, RNU6-952P, AP000942.5, BIRC3, BIRC2, TMEM123, AP001830.1, AP001830.2, MMP7, MMP20, AP000851.1, AP000851.2, MMP27, MMP8, WTAPP1, AP000619.1, AP000619.3, MMP10, MMP1, AP000619.2, MMP3, MMP12, BOLA3P1, RNU7-159P, MMP13.
- chr11:103,402,013–104,609,498, 14 genes, copy number 9–13 (within-gene range 2–13): MTCO3P15, MTATP6P15, MTCO2P15, MTCO1P15, MTND2P26, MTND1P36, AP003461.1, AP002989.1, MIR4693, PDGFD, AP003043.1, DDI1, AP003304.1, LINC02552.
- chr11:107,502,727–107,565,742, 1 gene, copy number 7 (within-gene range 2–7): ALKBH8.
- chr12:66,767–214,570, 7 genes, copy number 14 (within-gene range 2–14): IQSEC3, AC026369.3, AC026369.1, AC026369.2, AC007406.3, SLC6A12, AC007406.1.
- chr12:5,088,002–5,092,742, 1 gene, copy number 11: AC005906.3.
- chr12:16,188,485–16,277,685, 1 gene, copy number 9: SLC15A5.
- chr12:45,117,771–45,216,041, 4 genes, copy number 18: RNA5SP361, AC009248.3, PLEKHA8P1, AC009248.1.
- chr12:51,391,317–51,923,361, 13 genes, copy number 11–13 (within-gene range 2–13): SLC4A8, AC107031.1, SCN8A, HNRNPA3P10, AC068987.1, TMDD1, AC068987.2, FIGNL2, AC068987.3, FIGNL2-DT, ANKRD33, AC025259.2, ACVRL1.
- chr12:57,723,761–58,098,013, 27 genes, copy number 8–14: AGAP2, AGAP2-AS1, TSPAN31, CDK4, MIR6759, MARCHF9, CYP27B1, METTL1, EEF1AKMT3, AC025165.3, TSFM, AVIL, AC025165.5, RNU6-1083P, AC025165.4, CTDSP2, MIR26A2, AC083805.2, AC083805.1, AC083805.3, ATP23, GIHCG, AC084033.1, RN7SKP65, AC084033.2, LINC02403, AC090643.1.
- chr12:58,394,596–58,395,138, 1 gene, copy number 12: AC025578.1.
- chr12:64,939,023–64,939,117, 1 gene, copy number 13: RNU6ATAC42P.
- chr12:65,758,020–66,343,643, 20 genes, copy number 5–17 (within-gene range 2–17): RPSAP52, HMGA2, AC107308.1, HMGA2-AS1, AC090673.1, MIR6074, LINC02425, RPL21P18, RNA5SP362, LLPH, AC078927.1, LLPH-DT, TMBIM4, IRAK3, RBMS1P1, MIR6502, AC078889.1, PDCL3P7, RN7SKP166, HELB.
- chr12:66,563,524–66,569,194, 2 genes, copy number 9: OSBPL9P5, OSBPL9P4.
- chr12:68,610,855–68,671,901, 1 gene, copy number 12 (within-gene range 3–12): RAP1B.
- chr12:68,642,519–69,224,242, 16 genes, copy number 7–12: ATP5PDP4, AC090061.1, RPL7P42, NUP107, KRT8P39, SLC35E3, AC025423.3, MDM2, AC025423.1, AC025423.4, AC025423.2, CPM, RNU7-4P, AC025423.5, PRELID2P1, AC127894.1.
- chr12:69,326,574–69,959,097, 18 genes, copy number 6–12 (within-gene range 4–12): AC020656.2, LYZ, AC020656.1, YEATS4, RN7SL804P, RPS26P45, LINC02373, FRS2, MIR3913-1, MIR3913-2, CCT2, LRRC10, BEST3, AC025263.3, AC025263.1, RAB3IP, AC025263.2, MYRFL.
- chr12:75,480,753–75,503,863, 2 genes, copy number 6 (within-gene range 2–6): GLIPR1, AC121761.1.
- chr12:76,721,534–76,880,352, 5 genes, copy number 7: RPL7P43, AC093014.1, ZDHHC17, CSRP2, AC124784.1.
- chr12:77,129,178–78,213,010, 5 genes, copy number 8–15 (within-gene range 2–15): AC079030.1, LINC02464, NAV3, AC073591.1, AC138331.1.
- chr12:80,099,537–80,380,879, 1 gene, copy number 11 (within-gene range 2–11): OTOGL.
- chr12:80,343,515–80,343,792, 1 gene, copy number 11: RN7SKP261.
- chr12:81,953,719–82,515,817, 8 genes, copy number 6–22: LINC02426, AC011602.1, CCDC59, METTL25, AC089998.3, AC089998.4, AC089998.2, AC089998.1.

Autosomal genes at a single copy (total copy number 1): 1. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
